Gene-level copy-number profile of specimen HCM-STAN-0627-C34-85A from HCMI case HCM-STAN-0627-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 59.5 years (21,727 days).
Specimen HCM-STAN-0627-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 24e75f78-73df-4f91-b0a3-990cce8049ec.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-STAN-0627-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/925d7bfb-b178-4a05-969e-e68b3f5275b6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 14,043; copy number 2: 37,612; copy number 3: 4,932; copy number 4: 712; copy number 5: 930; copy number 6: 30; copy number 7: 247; copy number 8: 172; copy number 9: 28; copy number 10: 53; copy number 12: 41; copy number 13: 26; copy number 15: 2; copy number 16: 27; copy number 17: 40; copy number 18: 5; copy number 20: 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:41,578,903–41,579,186, 1 gene: RN7SL565P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,602 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:87,503,017–102,283,958, 326 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr7:111,726,110–112,206,407, 2 genes, copy number 5 (within-gene range 4–5): DOCK4, AC003077.1.
- chr7:111,953,653–111,971,988, 2 genes, copy number 5: RNA5SP237, AC003080.1.
- chr9:20,341,669–20,622,499, 1 gene, copy number 5 (within-gene range 3–5): MLLT3.
- chr9:20,502,265–21,031,640, 7 genes, copy number 5: MIR4474, AL163193.1, FOCAD, FOCAD-AS1, MIR491, SNORA30B, HACD4.
- chr11:68,707,440–78,574,874, 323 genes, copy number 8–20 (broad region; genes not listed).
- chr12:12,310–34,249,958, 834 genes, copy number 5–16 (broad region; genes not listed).
- chr21:12,999,676–18,267,373, 107 genes, copy number 5–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,699. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
